Somatic mutation profile of tumor specimen 0DS8GK from CCDI case PBCGIW, project CCDI-MCI: Molecular Characterization Initiative (MCI). Sex at birth: female; Primary diagnosis: Ependymoma, NOS; Tissue or organ of origin: Spinal meninges; Age at diagnosis: 12.6 years (4,587 days).
Specimen 0DS8GK: Tissue type: Tumor; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 27025e40-60f8-4f37-a46d-61411b669cfa.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 0DS8GT (Peripheral Whole Blood; tissue type Normal); read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/66eb0476-e079-4074-acac-b1c21d99d731

The open-access MAF lists 16 somatic variants for this specimen: 9 protein-altering or splice-affecting, 3 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 5, Silent 3, Frame Shift Ins 2, 5'UTR 2, Nonsense Mutation 1, Intron 1, Frame Shift Del 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- BORCS5 | c.544C>T p.R182W | Missense Mutation (SNP) | VAF 168/400 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.967); catalogued as rs761950808; called by muse, mutect2, varscan2
- DBR1 | c.902G>A p.R301H | Missense Mutation (SNP) | VAF 136/297 reads (46%) | SIFT tolerated (0.26); PolyPhen benign (0.003); catalogued as rs778482901, COSV53430087; called by muse, mutect2, varscan2
- FAM83B | c.85C>T p.R29* | Nonsense Mutation (SNP) | VAF 170/376 reads (45%) | catalogued as COSV60926254; called by muse, mutect2, varscan2
- OR8H3 | c.607G>T p.A203S | Missense Mutation (SNP) | VAF 32/624 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.279); catalogued as rs377459055; called by muse, mutect2
- TGFB1 | c.614G>A p.R205Q | Missense Mutation (SNP) | VAF 376/569 reads (66%) | SIFT tolerated (0.08); PolyPhen benign (0.121); catalogued as rs772469907, COSV55723750, COSV55723977; called by muse, mutect2, varscan2
- AHDC1 | c.1484dup p.S496Vfs*21 | Frame Shift Ins (INS) | VAF 163/428 reads (38%) | called by mutect2, pindel, varscan2
- ARHGAP23 | c.3955del p.A1319Rfs*56 | Frame Shift Del (DEL) | VAF 25/74 reads (34%) | called by mutect2, pindel, varscan2
- MTA3 | c.1255C>T p.P419S | Missense Mutation (SNP) | VAF 137/343 reads (40%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.996); called by muse, mutect2, varscan2
- MUC16 | c.34814_34818dup p.V11607Qfs*8 | Frame Shift Ins (INS) | VAF 55/195 reads (28%) | called by mutect2, pindel, varscan2
- CASP9 | c.984G>A p.Q328= | Silent (SNP) | VAF 192/438 reads (44%) | called by muse, mutect2, varscan2
- KIR2DL3 | c.597C>T p.F199= | Silent (SNP) | VAF 111/475 reads (23%) | catalogued as rs747953308; called by muse, mutect2, varscan2
- MCF2 | c.1614G>C p.L538= | Silent (SNP) | VAF 130/298 reads (44%) | called by muse, mutect2, varscan2
- PDE4DIP | c.-24G>A | 5'UTR (SNP) | VAF 10/27 reads (37%) | catalogued as rs782660593, COSV100519065; called by mutect2, varscan2
- RBPJL | c.*8C>T | 3'UTR (SNP) | VAF 163/353 reads (46%) | catalogued as rs765578435, COSV100643396; called by muse, mutect2, varscan2
- ZNF595 | c.-15C>G | 5'UTR (SNP) | VAF 36/500 reads (7%) | catalogued as COSV100227370; called by muse, mutect2
- ZP1 | c.1113-30C>T | Intron (SNP) | VAF 79/180 reads (44%) | called by muse, mutect2, varscan2
